Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BL, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BL-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

Specimens Submitted:

1: Right radical resection of deltoid sarcoma LS posterior; ss posterior

DIAGNOSIS:

1. Right deltoid; radical resection:
- High grade malignant fibrous histiocytoma, inflammatory and pleomorphic types, involving skeletal muscle.
- Tumor size: 5.6 x 2.8 x 2.2 cm.
- The surgical margins are free of tumor.
- The amount of gross necrosis is 5-10%.

NOTE: The tumor has a heterogenous morphologic appearance, with areas showing prominent inflammatory/lymphoid aggregates and Reed-Sternberg-like cells, admixed with other areas displaying spindled and pleomorphic cells arranged in a fascicular growth pattern. Immunohistochemical stains for CDK4 and MDM2 are negative. The inflammatory component is reactive in nature, as demonstrated by CD3, CD20, BCL2, kappa, lambda, and CD43. This case was reviewed in consultation with _____ who concurs.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh, labeled "right radical resection of deltoid sarcoma" and consists of an oriented portion of skin, subcutaneous tissue and skeletal muscle, overall dimensions 15 x 9.2 x 5.0cm. The ellipse of skin is 15 x 5.5cm, and is free of scars. On cut surface, there is a well-demarcated tumor located between the deep subcutis and into skeletal muscle, 5.6 x 2.8 x 2.2cm. The tumor has a white-tan bulging cut surface

** Continued on next page **

CONF ICD-O-3
Sarcoma, pleomorphic, undifferentiated
(8802/3) (8805/3)
Code to highest 8805/3
path
Histiocytoma, fibrous malignant 8830/3
Site (B) Shoulder NOS C49.1
JAD 11/22/13

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
with 5-10% gross necrosis.

Its relations are as follows: deep (black) 2.6cm; anterior (yellow) 1.8cm; posterior (green) 1.5cm; superior (blue) 3.0cm; inferior (purple) 3.6cm; and skin 1.1cm. Photographs are taken. Representative tissue is submitted for TPS and permanent sections.

Summary of sections:

SM- superior margin
IM - inferior margin
AM - anterior margin
PM - posterior margin
DM - deep margin
S - skin
T - tumor

Summary of Sections:

Part 1: Right radical resection of deltoid sarcoma LS posterior;
posterior

Block	Sect.	Site	PCs
1		AM	1
1		DM	1
1		IM	1
1		PM	1
1		S	1
1		SM	1
6		T	6

** End of Report **

Diagnostic Discrepancy		☒

Source: NCI Genomic Data Commons file 533b12a4-d3a8-4c3a-9c41-5097b5486bca (TCGA-DX-A8BL.FE8C19F5-3702-4BBF-BBC6-59D40A93C041.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).